CCDI case PBCFZF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/10ca7180-d5ca-42ec-9788-3cabd33cca7a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 12.7 years (4,654 days).

Biospecimens (3 samples)
- Sample 0DR9BP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR9C4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR9CR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
